Somatic mutation profile of tumor specimen MP2PRT-PARSPN-TMP1-A (aliquot MP2PRT-PARSPN-TMP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PARSPN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.9 years (683 days).
Specimen MP2PRT-PARSPN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63abdb7c-19f4-474e-a341-568c9f6a701e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARSPN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARSPN-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a31e47f-281f-4304-93ed-d83de8f600a8

The open-access MAF lists 18 somatic variants for this specimen: 11 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 9, Silent 7, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 35/333 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CDH19 | c.1861C>T p.R621W | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs749665230, COSV50968733; called by muse, mutect2, varscan2
- DNAH3 | c.7330G>A p.A2444T | Missense Mutation (SNP) | VAF 39/310 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs146558827; called by muse, mutect2, varscan2
- IRF2BP2 | c.910A>C p.T304P | Missense Mutation (SNP) | VAF 171/443 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.174); catalogued as rs1167428086; called by muse, mutect2
- PIMREG | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 134/480 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs762411331, COSV99338289; called by muse, mutect2, varscan2
- SYT12 | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 39/248 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.539); catalogued as rs201786852; called by muse, mutect2, varscan2
- TTN | c.18506A>T p.K6169I (on ENST00000591111; = p.K5242I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/194 reads (41%) | PolyPhen possibly damaging (0.568); catalogued as COSV100588729; called by mutect2, varscan2
- CUL4B | c.1557G>T p.L519F | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CUL4B | c.1556T>A p.L519* | Nonsense Mutation (SNP) | VAF 15/145 reads (10%) | called by muse, mutect2, varscan2
- GAL3ST1 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 96/433 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- TTN | c.18507del p.K6169Nfs*2 (on ENST00000591111; = p.K5242Nfs*2 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 80/233 reads (34%) | called by mutect2, pindel, varscan2
- ACTN2 | c.1395G>A p.A465= | Silent (SNP) | VAF 114/342 reads (33%) | catalogued as rs750674913, COSV63974194; called by muse, mutect2
- CFAP74 | c.4251C>T p.N1417= | Silent (SNP) | VAF 85/216 reads (39%) | catalogued as rs758822438; called by muse, mutect2, varscan2
- RFPL2 | c.609C>T p.D203= | Silent (SNP) | VAF 65/252 reads (26%) | catalogued as rs753078382, COSV50710845; called by muse, mutect2, varscan2
- RHBDF1 | c.663G>A p.A221= | Silent (SNP) | VAF 29/201 reads (14%) | catalogued as rs753533650; called by muse, mutect2, varscan2
- SPEN | c.7722G>A p.P2574= | Silent (SNP) | VAF 22/381 reads (6%) | catalogued as rs772191071; called by muse, mutect2
- TMEM132B | c.318A>C p.T106= | Silent (SNP) | VAF 37/352 reads (11%) | catalogued as rs765546763; called by muse, mutect2, varscan2
- TSGA10IP | c.294G>A p.P98= | Silent (SNP) | VAF 21/240 reads (9%) | catalogued as rs757122514, COSV73245439; called by muse, mutect2
